Somatic mutation profile of tumor specimen ALCH-B1YQ-TTP1-A (aliquot ALCH-B1YQ-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B1YQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 52.5 years (19,165 days).
Specimen ALCH-B1YQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6d20b27-60a4-4f7a-bf21-60ac1d664e5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YQ-NB1-A (Blood Derived Normal), aliquot ALCH-B1YQ-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fb86e3a-f79d-4aeb-b36f-c2542c2b5419

The open-access MAF lists 528 somatic variants for this specimen: 378 protein-altering or splice-affecting, 87 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 327, Silent 87, Intron 30, Nonsense Mutation 25, RNA 12, Splice Site 11, 3'UTR 9, Frame Shift Del 9, 5'UTR 6, 3'Flank 4, Splice Region 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 73/288 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; called by muse, mutect2, varscan2
- ACSM6 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1239634700; called by muse, mutect2
- ADAMTS12 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201968522; called by muse, varscan2
- ADCY8 | c.3307del p.A1103Lfs*13 | Frame Shift Del (DEL) | VAF 43/236 reads (18%) | catalogued as COSV53895807; called by mutect2, pindel, varscan2
- ADGRG4 | c.3713G>T p.R1238L | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54959906, COSV99795140; called by muse, mutect2
- AFF2 | c.2378G>C p.R793P | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV99663239; called by muse, mutect2
- AHNAK | c.15782C>T p.S5261F | Missense Mutation (SNP) | VAF 37/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771792360; called by muse, mutect2, varscan2
- AL121899.2 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV67349961; called by muse, mutect2
- ANKRD11 | c.6893G>T p.R2298L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs1304326484; ClinVar: uncertain significance; called by muse, varscan2
- ANKS1B | c.1877A>G p.Y626C | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs747220515; called by muse, mutect2, varscan2
- ARC | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV63078810; called by muse, mutect2, varscan2
- ARPP21 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV51796511; called by muse, mutect2, varscan2
- ATOH8 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as rs781504178; called by muse, mutect2, varscan2
- BRWD3 | c.1813G>T p.V605L | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1411726595, COSV100956158; called by muse, mutect2
- CACNA1E | c.6055C>G p.R2019G (on ENST00000367573 / NM_001205293.3; = p.R1976G on NM_000721.4) | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62388920; called by muse, mutect2
- CACNA1F | c.1830G>T p.L610F | Missense Mutation (SNP) | VAF 40/463 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59906360; called by muse, mutect2
- CASP8AP2 | c.3912A>T p.L1304F | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52747307; called by muse, mutect2
- CAV1 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 18/240 reads (8%) | catalogued as COSV61952412; called by muse, mutect2
- CD79B | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 44/542 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as rs868652684, COSV50076455, COSV50077867; called by muse, mutect2
- CDH16 | c.1707C>A p.Y569* | Nonsense Mutation (SNP) | VAF 26/182 reads (14%) | catalogued as COSV100234350; called by muse, mutect2, varscan2
- CDO1 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV51664244; called by muse, varscan2
- CEMIP2 | c.2869G>T p.V957L | Missense Mutation (SNP) | VAF 61/422 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV100987123; called by muse, varscan2
- CFAP91 | c.1820G>T p.R607L | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99847345; called by muse, mutect2, varscan2
- CNTN6 | c.56-1G>T p.X19_splice | Splice Site (SNP) | VAF 7/52 reads (13%) | catalogued as COSV63179958; called by mutect2, varscan2
- COL5A3 | c.1657G>T p.D553Y | Missense Mutation (SNP) | VAF 73/470 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53419960; called by muse, mutect2, varscan2
- CUBN | c.6341C>T p.S2114F | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV64711459; called by muse, mutect2
- CYP2W1 | c.1078C>T p.L360F | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1367473430; called by muse, mutect2
- DES | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1025323214; called by muse, mutect2
- DNAH3 | c.8336C>A p.P2779Q | Missense Mutation (SNP) | VAF 48/718 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.365); catalogued as COSV54531091; called by muse, mutect2
- EBLN1 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 17/269 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs578105624, COSV69370217; called by muse, mutect2
- ELF4 | c.1714G>C p.D572H | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.456); catalogued as COSV100257509; called by muse, mutect2
- ENPEP | c.2195G>A p.G732E | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as rs1246067314; called by muse, mutect2
- FAM171B | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 13/252 reads (5%) | catalogued as COSV59007831; called by muse, mutect2
- FAM24A | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.874); catalogued as rs148129366; called by muse, mutect2, varscan2
- FAM47B | c.279G>C p.R93S | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as COSV61456078; called by muse, mutect2
- FAP | c.1138A>G p.I380V | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV51868174; called by muse, mutect2, varscan2
- FRAS1 | c.7081G>C p.E2361Q | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as COSV53637536; called by muse, varscan2
- GABRB3 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100158579; called by muse, mutect2, varscan2
- GABRB3 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 43/293 reads (15%) | catalogued as COSV54689165; called by muse, mutect2, varscan2
- GALNT2 | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs949092593, COSV64195338; called by muse, varscan2
- GLI3 | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 83/551 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs140479817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPD2 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV60096690; called by muse, mutect2
- GPR156 | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 21/261 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs199714569; called by muse, mutect2
- GPR65 | c.25C>G p.Q9E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.23); catalogued as COSV50862941; called by muse, mutect2, varscan2
- GRIN2B | c.3898C>G p.R1300G | Missense Mutation (SNP) | VAF 50/408 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74206505; called by muse, mutect2, varscan2
- HCN1 | c.2581C>A p.P861T | Missense Mutation (SNP) | VAF 59/378 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.188); catalogued as rs756753787, COSV57521091, COSV57526712; called by muse, mutect2, varscan2
- HHIPL1 | c.2200G>T p.G734C | Missense Mutation (SNP) | VAF 94/400 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.775); catalogued as rs757133224, COSV100415218; called by muse, mutect2, varscan2
- HMCN1 | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54919404; called by muse, mutect2
- IGSF8 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 46/810 reads (6%) | catalogued as COSV100081800; called by muse, mutect2
- IRX1 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs777536117, COSV100116681; called by muse, mutect2, varscan2
- KCND2 | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58567542, COSV58590964; called by muse, mutect2
- KIF2B | c.1774C>G p.Q592E | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52128578, COSV52129153; called by muse, mutect2
- KRT76 | c.210C>A p.S70R | Missense Mutation (SNP) | VAF 152/739 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60121711; called by muse, mutect2, varscan2
- KRTAP13-2 | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs765413129, COSV67762412; called by muse, varscan2
- L1CAM | c.570C>G p.N190K | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV100649118; called by muse, mutect2
- LCT | c.2701G>A p.G901R | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776158841; called by muse, mutect2, varscan2
- LILRB4 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 136/450 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as COSV54405014; called by muse, mutect2, varscan2
- LRRIQ1 | c.2939A>C p.Q980P | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs1186569482; called by muse, mutect2
- MAGEC1 | c.2383C>G p.H795D | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.027); catalogued as COSV53567556; called by muse, mutect2
- MAST3 | c.2525G>T p.R842L | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.581); catalogued as COSV53220779; called by muse, mutect2, varscan2
- MCTP1 | c.44C>A p.A15E | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.238); catalogued as rs1238318183; called by muse, varscan2
- MDN1 | c.5626G>T p.G1876W | Missense Mutation (SNP) | VAF 41/347 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451841795; called by muse, mutect2, varscan2
- MSN | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 37/546 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV100814285; called by muse, mutect2
- MUC6 | c.1282del p.Q428Sfs*37 | Frame Shift Del (DEL) | VAF 38/308 reads (12%) | catalogued as COSV70150622; called by mutect2, pindel, varscan2
- MYH13 | c.4639G>T p.A1547S | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as rs761657838, COSV52837166; called by muse, mutect2, varscan2
- MYH7 | c.2416G>T p.E806* | Nonsense Mutation (SNP) | VAF 126/659 reads (19%) | catalogued as COSV62517814, COSV62518010; called by muse, mutect2, varscan2
- NAV2 | c.1306G>T p.G436C (on ENST00000396087 / NM_001244963.2; = p.G413C on NM_145117.5) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs749299835; called by muse, mutect2, varscan2
- NEXMIF | c.4304G>C p.S1435T | Missense Mutation (SNP) | VAF 19/274 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV50024097, COSV99281473; called by muse, mutect2
- NPY1R | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56715111; called by muse, mutect2
- OGFR | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 55/660 reads (8%) | catalogued as COSV51700797; called by muse, mutect2
- OR10K1 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 24/572 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as rs1309095995; called by muse, mutect2
- OR10S1 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 32/475 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV73342669; called by muse, mutect2
- OR2C3 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63574545; called by muse, mutect2
- OR2L5 | c.444G>C p.W148C | Missense Mutation (SNP) | VAF 79/431 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV62364577, COSV62364847; called by muse, mutect2, varscan2
- OR2Z1 | c.321G>T p.M107I | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs782795539, COSV60691905; called by muse, mutect2, varscan2
- OR4C12 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58860706; called by muse, mutect2
- OR52E8 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV66206347; called by muse, mutect2, varscan2
- OR6F1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs779408792; called by muse, mutect2
- OR8B12 | c.703A>G p.K235E | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60912631; called by muse, mutect2, varscan2
- OR8J3 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56883960; called by muse, mutect2, varscan2
- PAQR9 | c.583C>A p.R195S | Missense Mutation (SNP) | VAF 110/454 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs750531203, COSV61417840; called by muse, mutect2, varscan2
- PARP3 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs761144798; called by muse, mutect2
- PCDH12 | c.2942G>A p.R981Q | Missense Mutation (SNP) | VAF 65/436 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746075397; called by muse, mutect2, varscan2
- PCDHB12 | c.2111C>G p.S704W | Missense Mutation (SNP) | VAF 50/618 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as rs1347203547, COSV53395531; called by muse, mutect2
- PDSS1 | c.228-1G>T p.X76_splice | Splice Site (SNP) | VAF 37/305 reads (12%) | catalogued as COSV100873625; called by muse, mutect2, varscan2
- PFKM | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 84/469 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV56658766; called by muse, mutect2, varscan2
- PHTF2 | c.1190G>T p.R397M (on ENST00000248550 / NM_001366089.1; = p.R359M on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99301854; called by muse, mutect2, varscan2
- PIAS4 | c.149G>T p.C50F | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as COSV53680489; called by muse, mutect2, varscan2
- PIP5K1C | c.1682G>T p.R561M | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV58955128; called by muse, mutect2, varscan2
- PLCD4 | c.1489G>T p.V497F | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68743904; called by muse, mutect2, varscan2
- PLEKHB2 | c.821T>A p.L274Q | Missense Mutation (SNP) | VAF 22/144 reads (15%) | PolyPhen possibly damaging (0.766); catalogued as rs1352530422; called by muse, mutect2, varscan2
- PLPPR3 | c.1363G>A p.E455K (on ENST00000520876 / NM_001270366.2; = p.E483K on NM_024888.2) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.281); catalogued as rs1276556344; called by muse, mutect2, varscan2
- PPFIA4 | c.2657G>C p.R886P (on ENST00000447715; = p.R887P on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/658 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99691202; called by muse, mutect2, varscan2
- PPP4R3C | c.1987G>T p.V663L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV69081082; called by muse, mutect2
- PRB2 | c.136A>G p.K46E | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.188); catalogued as COSV66982594; called by muse, mutect2
- RANBP17 | c.1648C>G p.L550V | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV66653221; called by muse, mutect2, varscan2
- RP1L1 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs374232439; called by muse, mutect2, varscan2
- RRP8 | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV54449007; called by muse, mutect2, varscan2
- RSPO1 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 112/435 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100740707; called by muse, mutect2, varscan2
- RXFP3 | c.1196C>A p.A399E | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV57506435; called by muse, mutect2, varscan2
- SALL1 | c.3184G>C p.E1062Q | Missense Mutation (SNP) | VAF 62/975 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV51758759; called by muse, mutect2
- SDHA | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 112/648 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.134); catalogued as COSV53766392; called by muse, mutect2, varscan2
- SDK1 | c.2426G>T p.R809L | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs756442334, COSV67362060; called by muse, mutect2
- SEMA3D | c.755C>G p.T252S | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.922); catalogued as COSV52394164; called by muse, mutect2, varscan2
- SIGLEC14 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 164/486 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99708039; called by muse, mutect2, varscan2
- SIK2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1328996537, COSV104396254; called by muse, mutect2
- SLC30A8 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs777302856, COSV69969419, COSV69969771; called by muse, mutect2, varscan2
- SLCO1B3 | c.541C>A p.R181S | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53933044; called by muse, mutect2, varscan2
- SMARCA1 | c.734A>C p.H245P | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1325954114; called by muse, mutect2
- SMTNL1 | c.1340T>A p.V447E (on ENST00000399154; = p.V484E on NM_001105565.2) | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54703227; called by muse, mutect2, varscan2
- SNAP91 | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs765646597; called by muse, mutect2
- SPAG6 | c.1363G>A p.G455S | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.356); catalogued as COSV100510420; called by muse, mutect2, varscan2
- SPEG | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 77/635 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV56663544; called by muse, mutect2, varscan2
- STK26 | c.1122G>C p.R374S | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV100049030; called by muse, mutect2
- TAS2R14 | c.19A>T p.S7C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as COSV67854403; called by muse, mutect2, varscan2
- THAP1 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs759430545; called by muse, mutect2
- TIGAR | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 39/322 reads (12%) | catalogued as COSV51629674, COSV99464138; called by muse, mutect2, varscan2
- TNFSF15 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65010899; called by muse, varscan2
- TNXB | c.8233+1G>T p.X2745_splice (on ENST00000647633; = p.X2498_splice on NM_019105.8 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/118 reads (15%) | catalogued as COSV64488035; called by muse, mutect2
- TP53INP2 | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV66351379; called by muse, mutect2, varscan2
- TRANK1 | c.6409C>G p.R2137G | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV57155121; called by muse, mutect2, varscan2
- TSC2 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 36/718 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.416); catalogued as rs773920155, COSV54771227; called by muse, mutect2
- TTBK1 | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 31/303 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.185); catalogued as COSV99443361; called by muse, mutect2
- TTN | c.53734C>T p.R17912W (on ENST00000591111; = p.R10488W on NM_003319.4) | Missense Mutation (SNP) | VAF 22/305 reads (7%) | PolyPhen probably damaging (0.917); catalogued as rs372959465, COSV59884908, COSV60001200; called by muse, mutect2
- TTN | c.53062G>A p.E17688K (on ENST00000591111; = p.E10264K on NM_003319.4) | Missense Mutation (SNP) | VAF 17/141 reads (12%) | PolyPhen benign (0.154); catalogued as COSV100615946; called by muse, mutect2, varscan2
- TTN | c.45764C>T p.T15255I (on ENST00000591111; = p.T7831I on NM_003319.4) | Missense Mutation (SNP) | VAF 45/403 reads (11%) | PolyPhen probably damaging (0.998); catalogued as COSV100627065; called by muse, mutect2, varscan2
- TTN | c.5716G>C p.D1906H (on ENST00000591111; = p.D1860H on NM_003319.4) | Missense Mutation (SNP) | VAF 19/167 reads (11%) | PolyPhen probably damaging (0.999); catalogued as COSV59912368; called by muse, mutect2, varscan2
- TTN | c.3031G>C p.G1011R (on ENST00000591111; = p.G965R on NM_003319.4) | Missense Mutation (SNP) | VAF 27/246 reads (11%) | PolyPhen probably damaging (1); catalogued as COSV100591241; called by muse, mutect2, varscan2
- TTN | c.1015C>A p.P339T | Missense Mutation (SNP) | VAF 29/263 reads (11%) | PolyPhen benign (0.001); catalogued as COSV60325616; called by muse, mutect2, varscan2
- USP29 | c.1428C>G p.F476L | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54143882; called by muse, mutect2, varscan2
- VWF | c.7571C>T p.P2524L | Missense Mutation (SNP) | VAF 27/347 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs374690023; called by muse, mutect2
- WBP1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs772644106, COSV51972326; called by muse, mutect2, varscan2
- XIRP2 | c.91C>T p.R31W (on ENST00000628543; = p.R206W on NM_152381.6) | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1375329184, COSV54699057, COSV54700656; called by muse, mutect2
- ZC3H12B | c.1935G>T p.E645D | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1331585190; called by muse, mutect2
- ZFHX4 | c.10544A>G p.Y3515C | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.719); catalogued as rs759968003; called by muse, mutect2
- ZNF208 | c.1090A>T p.T364S | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV68108278; called by muse, mutect2, varscan2
- ZNF749 | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61945064; called by muse, mutect2, varscan2
- A1CF | c.155C>G p.P52R | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2
- AASDH | c.1104-1G>A p.X368_splice | Splice Site (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- ABCC9 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- ABCD1 | c.651G>T p.K217N | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCG5 | c.1601T>A p.V534E | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ACACA | c.6124G>T p.D2042Y | Missense Mutation (SNP) | VAF 80/562 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ACCSL | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 47/474 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACSM4 | c.1078G>T p.V360L | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, varscan2
- ADAM2 | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- ADAMTS12 | c.1336C>A p.R446= | Splice Region (SNP) | VAF 18/98 reads (18%) | called by muse, varscan2
- ADAMTS19 | c.543C>A p.D181E | Missense Mutation (SNP) | VAF 27/393 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.03); called by muse, mutect2
- ADCY8 | c.290del p.G97Efs*88 | Frame Shift Del (DEL) | VAF 11/105 reads (10%) | called by mutect2, pindel, varscan2
- ADGB | c.1867dup p.T623Nfs*3 | Frame Shift Ins (INS) | VAF 24/204 reads (12%) | called by mutect2, pindel, varscan2
- ADGRD2 | c.2611C>A p.L871M | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- AFF2 | c.1441A>T p.S481C | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2
- AGMO | c.218T>C p.L73S | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, varscan2
- AK5 | c.783G>T p.Q261H (on ENST00000354567 / NM_174858.3; = p.Q235H on NM_012093.4) | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AK7 | c.349T>C p.Y117H | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD12 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.984); called by muse, varscan2
- ANKRD13B | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- APOLD1 | c.457G>T p.E153* (on ENST00000326765 / NM_001130415.2; = p.E122* on NM_030817.3) | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | called by muse, mutect2, varscan2
- ARMCX5 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.427); called by muse, mutect2
- ASTN2 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 43/250 reads (17%) | called by muse, mutect2, varscan2
- ATP11C | c.1544T>A p.F515Y | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP1A2 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 92/491 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AUTS2 | c.3740G>T p.R1247M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); called by muse, varscan2
- BOD1L1 | c.2026G>T p.V676L | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- BRD2 | c.2237A>T p.Q746L | Missense Mutation (SNP) | VAF 60/447 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, varscan2
- C10orf71 | c.1456T>G p.C486G | Missense Mutation (SNP) | VAF 20/261 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- C1QTNF7 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- C6orf118 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 14/161 reads (9%) | called by muse, mutect2
- CALCOCO2 | c.1331A>C p.H444P | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBY2 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 82/470 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- CFAP94 | c.2015T>G p.F672C (on ENST00000320267 / NM_001352064.2; = p.F678C on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- CHMP4C | c.648G>T p.Q216H | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- CHRNA6 | c.702C>A p.F234L | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CHST1 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHSY1 | c.1288A>T p.K430* | Nonsense Mutation (SNP) | VAF 103/625 reads (16%) | called by muse, mutect2, varscan2
- CIP2A | c.1136G>T p.C379F | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.094); called by muse, varscan2
- CLEC17A | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CLEC17A | c.199+1G>T p.X67_splice | Splice Site (SNP) | VAF 35/218 reads (16%) | called by muse, mutect2, varscan2
- CNBD1 | c.1217G>T p.S406I | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CNGA3 | c.452A>C p.K151T | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CORIN | c.2397C>A p.N799K | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPNE1 | c.469A>T p.K157* (on ENST00000352393; = p.K162* on NM_003915.5) | Nonsense Mutation (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- CSTF2T | c.1482G>T p.Q494H | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- CYLC1 | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- DACH2 | c.863C>A p.A288D | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.079); called by muse, mutect2
- DHX30 | c.314A>G p.K105R (on ENST00000445061 / NM_138615.3; = p.K66R on NM_014966.3) | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DIP2A | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 19/279 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.244); called by muse, mutect2
- DLG5 | c.5378G>T p.R1793L | Missense Mutation (SNP) | VAF 42/411 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNMBP | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK4 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 33/516 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.045); called by muse, mutect2
- DONSON | c.663G>T p.W221C | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DONSON | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ECEL1 | c.1767G>T p.Q589H | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- EFNB2 | c.186C>A p.C62* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | called by muse, mutect2
- EIF2AK1 | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 46/638 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- EIF3M | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); called by muse, mutect2
- EIF4E | c.538G>T p.G180W | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELAVL1 | c.965A>T p.N322I | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, varscan2
- ELAVL2 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELFN1 | c.498C>A p.N166K | Missense Mutation (SNP) | VAF 30/393 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EMSY | c.2677T>A p.S893T | Missense Mutation (SNP) | VAF 30/482 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- ENKUR | c.243C>G p.N81K | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EP400 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM180A | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FBN3 | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- FBRSL1 | c.1836G>T p.M612I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2
- FCGBP | c.10306G>T p.G3436C | Missense Mutation (SNP) | VAF 275/759 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FGF23 | c.233A>G p.E78G | Missense Mutation (SNP) | VAF 26/407 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- FLG2 | c.6702C>A p.H2234Q | Missense Mutation (SNP) | VAF 73/499 reads (15%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- FN1 | c.4456+7C>A | Splice Region (SNP) | VAF 23/228 reads (10%) | called by muse, mutect2, varscan2
- FSIP2 | c.6555G>T p.L2185F | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- FZD8 | c.1045G>T p.G349C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); called by muse, varscan2
- GALNT6 | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLYATL1 | c.-166-2A>T | Splice Site (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- GNRHR | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- GOLGA6C | c.1965A>T p.E655D | Missense Mutation (SNP) | VAF 50/423 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1876C>A p.Q626K | Missense Mutation (SNP) | VAF 142/2394 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2
- GPC2 | c.1313A>T p.Y438F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- GPR158 | c.1682A>T p.Q561L | Missense Mutation (SNP) | VAF 23/300 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.115); called by muse, mutect2
- GRIA4 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, varscan2
- GRID2 | c.38G>T p.W13L | Missense Mutation (SNP) | VAF 55/564 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- GRIPAP1 | c.2321G>T p.G774V | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.299); called by muse, mutect2
- GRM1 | c.1184C>G p.T395R | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, mutect2
- GRM7 | c.2302G>A p.V768I | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GUCY1B1 | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- GUCY2F | c.2498G>T p.S833I | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- GUF1 | c.836T>G p.V279G | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.053); called by muse, mutect2
- HEPH | c.42G>T p.Q14H (on ENST00000343002; = p.Q68H on NM_138737.5) | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- HMCN1 | c.15844C>A p.Q5282K | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.721); called by muse, mutect2
- HNF4A | c.1176C>A p.H392Q | Missense Mutation (SNP) | VAF 84/478 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- HOXB2 | c.455A>T p.N152I | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- HTN1 | c.82G>C p.G28R | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.006); called by muse, mutect2
- ICA1 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- IFT52 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IMPG2 | c.2641G>T p.A881S | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.162); called by muse, mutect2
- IQCA1 | c.1768A>T p.T590S | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); called by muse, mutect2
- IRAK3 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ITGA8 | c.2402C>T p.P801L | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAG2 | c.3664G>T p.D1222Y | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNJ3 | c.237G>C p.K79N | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); called by muse, mutect2
- KCNJ4 | c.129G>T p.M43I | Missense Mutation (SNP) | VAF 50/324 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KCNQ2 | c.682del p.H228Tfs*45 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, varscan2
- KIF14 | c.4888G>T p.G1630C | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- KIF14 | c.2747dup p.I917Yfs*3 | Frame Shift Ins (INS) | VAF 48/324 reads (15%) | called by pindel, varscan2
- KLHL14 | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHL4 | c.244C>G p.P82A | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2
- KNDC1 | c.4016G>T p.S1339I | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KRR1 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- KRTAP21-2 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LARP7 | c.779G>C p.G260A | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.079); called by muse, mutect2
- LRRN3 | c.1568G>A p.G523D | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.11); called by muse, mutect2
- LTA4H | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 38/414 reads (9%) | called by muse, mutect2
- LY6G6E | c.124G>T p.V42F | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MAP1A | c.5664_5666del p.A1889del | In Frame Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- MBOAT1 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MDGA2 | c.1039G>C p.V347L (on ENST00000399232 / NM_001113498.2; = p.V49L on NM_182830.4) | Missense Mutation (SNP) | VAF 56/348 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MED12L | c.1539G>T p.W513C | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MFAP3L | c.587A>C p.E196A | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MINAR1 | c.1694C>G p.T565S | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOBP | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 68/341 reads (20%) | PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MROH2B | c.4194+1G>T p.X1398_splice | Splice Site (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- MSANTD4 | c.306T>A p.D102E | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MUC5B | c.1532T>A p.L511Q | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- MYH6 | c.3445A>G p.S1149G | Missense Mutation (SNP) | VAF 71/604 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO7B | c.3874C>A p.P1292T | Missense Mutation (SNP) | VAF 37/504 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYO7B | c.3875C>A p.P1292H | Missense Mutation (SNP) | VAF 37/499 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2
- NAT16 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2
- NBEAL2 | c.4198G>C p.A1400P | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, varscan2
- NCAM2 | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2
- NEDD4 | c.471T>A p.S157R | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); called by muse, varscan2
- NEK1 | c.465-2A>T p.X155_splice | Splice Site (SNP) | VAF 19/221 reads (9%) | called by muse, mutect2
- NFXL1 | c.573G>T p.W191C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NID2 | c.3524C>A p.A1175E | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- NPHS1 | c.1082G>A p.C361Y | Missense Mutation (SNP) | VAF 32/516 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NR1I2 | c.1199T>G p.L400R | Missense Mutation (SNP) | VAF 86/760 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NR4A2 | c.1715G>T p.R572L | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OPCML | c.752T>A p.M251K | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2
- OPTN | c.855G>C p.E285D | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.106); called by muse, mutect2
- OR10D3 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 64/420 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OR2AE1 | c.308T>G p.L103R | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- OR2G6 | c.343T>A p.L115M | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- OR4C15 | c.825G>T p.L275F (on ENST00000314644; = p.L221F on NM_001001920.2) | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR51E1 | c.353T>G p.L118R | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR8G2P | c.516T>G p.N172K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2
- OXER1 | c.899T>A p.V300E | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PAGE2B | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PAGE2B | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2
- PARVG | c.966G>T p.R322S | Missense Mutation (SNP) | VAF 78/421 reads (19%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAX7 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 132/617 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA5 | c.2254A>T p.T752S | Missense Mutation (SNP) | VAF 91/578 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- PCLO | c.12863G>T p.R4288M | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCM1 | c.3887A>T p.K1296M | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCNX3 | c.5215G>A p.A1739T | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PDE4DIP | c.5218G>A p.A1740T | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- PHIP | c.2488G>T p.G830* | Nonsense Mutation (SNP) | VAF 30/460 reads (7%) | called by muse, mutect2
- PIEZO2 | c.559G>C p.G187R | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.049); called by muse, mutect2
- PIK3R1 | c.347del p.P116Rfs*61 | Frame Shift Del (DEL) | VAF 28/268 reads (10%) | called by mutect2, varscan2
- PKHD1 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEK | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PLEKHA7 | c.714G>T p.M238I | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- PLXNA3 | c.3991C>A p.R1331S | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.171); called by muse, mutect2
- PMFBP1 | c.2530A>G p.K844E (on ENST00000537465; = p.K839E on NM_031293.3) | Missense Mutation (SNP) | VAF 50/369 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PMFBP1 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- PNMA5 | c.392C>G p.A131G | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.146); called by muse, mutect2
- POSTN | c.1243+1G>T p.X415_splice | Splice Site (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- POTEH | c.1174del p.Q392Sfs*12 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, varscan2
- POU6F2 | c.784C>A p.Q262K | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); called by muse, mutect2
- PPP1R2B | c.159G>C p.L53F | Missense Mutation (SNP) | VAF 148/768 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPP1R3F | c.2216del p.P739Qfs*7 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- PRG4 | c.2627C>A p.S876* | Nonsense Mutation (SNP) | VAF 106/489 reads (22%) | called by muse, mutect2, varscan2
- PROX1 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRR14L | c.434A>T p.Q145L | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); called by muse, mutect2
- PSMD8 | c.76G>T p.V26F | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PTCHD1 | c.525C>A p.Y175* | Nonsense Mutation (SNP) | VAF 26/312 reads (8%) | called by muse, mutect2
- RAB3GAP1 | c.1150G>C p.V384L | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RABL2A | c.25A>T p.S9C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0); called by mutect2, varscan2
- RIBC2 | c.295A>C p.I99L | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RLIM | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2
- RNF130 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- RPL10 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 58/610 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- RTN3 | c.2863G>T p.V955F (on ENST00000377819 / NM_001265589.2; = p.V159F on NM_006054.4) | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RYR1 | c.3448T>C p.C1150R | Missense Mutation (SNP) | VAF 200/643 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SASH3 | c.1097G>C p.G366A | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- SCRN1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 37/380 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SEC61A2 | c.886G>C p.A296P | Missense Mutation (SNP) | VAF 91/847 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SERPINB11 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, varscan2
- SETD1A | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 55/308 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SIX2 | c.560+2T>C p.X187_splice | Splice Site (SNP) | VAF 46/404 reads (11%) | called by muse, mutect2, varscan2
- SLC20A1 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- SLC22A12 | c.597C>A p.Y199* | Nonsense Mutation (SNP) | VAF 74/490 reads (15%) | called by muse, mutect2, varscan2
- SLC38A5 | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- SLC7A5 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 23/640 reads (4%) | called by muse, mutect2
- SMARCA4 | c.3243del p.K1081Nfs*25 | Frame Shift Del (DEL) | VAF 126/752 reads (17%) | called by mutect2, pindel, varscan2
- SPATA18 | c.1117A>T p.N373Y | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- SPATA31D1 | c.902C>A p.P301Q | Missense Mutation (SNP) | VAF 64/422 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- SPEG | c.5398G>A p.E1800K | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTA1 | c.5250C>A p.N1750K | Missense Mutation (SNP) | VAF 79/417 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SSX1 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2
- STRN3 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAB1 | c.1039del p.E347Sfs*12 | Frame Shift Del (DEL) | VAF 39/293 reads (13%) | called by mutect2, pindel, varscan2
- TAB3 | c.544C>G p.P182A | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2
- TBRG1 | c.1054A>T p.I352F | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- TENM3 | c.3740C>G p.A1247G | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- TGS1 | c.2303G>A p.G768E | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THSD7B | c.2132G>T p.G711V | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- THTPA | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM132D | c.1789C>A p.L597M | Missense Mutation (SNP) | VAF 52/618 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.116); called by muse, mutect2
- TMEM132D | c.1788C>A p.H596Q | Missense Mutation (SNP) | VAF 52/630 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2
- TMPRSS15 | c.1939C>A p.H647N | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- TNFAIP8L2 | c.156C>A p.S52R | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2
- TNR | c.735C>A p.C245* | Nonsense Mutation (SNP) | VAF 27/377 reads (7%) | called by muse, mutect2
- TOGARAM2 | c.2295G>T p.E765D | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- TRO | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 46/638 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TSHZ1 | c.1823G>T p.G608V (on ENST00000580243 / NM_001308210.2; = p.G563V on NM_005786.6) | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- TSSC4 | c.234G>T p.Q78H | Missense Mutation (SNP) | VAF 12/221 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- TTN | c.64792+5G>T | Splice Region (SNP) | VAF 33/263 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.39673G>A p.E13225K (on ENST00000591111; = p.E5801K on NM_003319.4) | Missense Mutation (SNP) | VAF 43/468 reads (9%) | PolyPhen possibly damaging (0.6); called by muse, mutect2
- TTN | c.18716C>A p.S6239* (on ENST00000591111; = p.S5312* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- U2SURP | c.2296G>T p.E766* | Nonsense Mutation (SNP) | VAF 25/164 reads (15%) | called by muse, mutect2, varscan2
- UBE3A | c.1552C>T p.Q518* | Nonsense Mutation (SNP) | VAF 14/177 reads (8%) | called by muse, mutect2
- UGT2B15 | c.1368G>C p.K456N | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- UNC80 | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USH1C | c.1086G>T p.Q362H | Missense Mutation (SNP) | VAF 34/552 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2
- USH2A | c.13388C>A p.T4463N | Missense Mutation (SNP) | VAF 53/399 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- VPS8 | c.1598-1G>T p.X533_splice (on ENST00000625842 / NM_001349294.1; = p.X531_splice on NM_015303.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 29/182 reads (16%) | called by muse, mutect2, varscan2
- WASHC2C | c.835A>C p.T279P | Missense Mutation (SNP) | VAF 62/618 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, varscan2
- WDR13 | c.338G>T p.S113I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- XK | c.1036G>T p.V346L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); called by muse, mutect2
- ZBTB22 | c.835G>C p.A279P | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- ZBTB4 | c.2053G>C p.G685R | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ZCCHC12 | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); called by muse, mutect2
- ZCCHC18 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 14/319 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2
- ZFHX4 | c.6931C>A p.Q2311K | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2
- ZFP92 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- ZIC3 | c.383G>T p.S128I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF461 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2
- ZNF711 | c.1765A>T p.T589S | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2
- ZNF717 | c.1987A>T p.T663S | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.031); called by muse, mutect2
- ABCA4 | c.1854G>T p.G618= | Silent (SNP) | VAF 101/433 reads (23%) | catalogued as rs1304041034; called by muse, mutect2, varscan2
- ACTL7B | c.1107A>C p.A369= | Silent (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- ADGB | c.756C>A p.I252= | Silent (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- AL136295.3 | c.543A>T p.S181= | Silent (SNP) | VAF 26/154 reads (17%) | called by muse, varscan2
- ANO2 | c.663G>A p.K221= (on ENST00000356134 / NM_001278597.3; = p.K225= on NM_001278596.3) | Silent (SNP) | VAF 28/401 reads (7%) | catalogued as rs1203285678; called by muse, mutect2
- ARMC5 | c.165G>A p.A55= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as rs757625031; called by muse, mutect2, varscan2
- ATP6V1A | c.1236A>G p.P412= | Silent (SNP) | VAF 28/201 reads (14%) | called by muse, mutect2, varscan2
- BCL11B | c.1773G>A p.K591= (on ENST00000357195 / NM_001282237.2; = p.K520= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/616 reads (7%) | called by muse, mutect2
- BIN1 | c.75G>T p.A25= | Silent (SNP) | VAF 16/340 reads (5%) | catalogued as rs995711961; called by muse, mutect2
- CFAP65 | c.1398C>T p.S466= | Silent (SNP) | VAF 22/146 reads (15%) | called by muse, mutect2
- CHST7 | c.705C>A p.R235= | Silent (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- CLCN5 | c.1497C>T p.P499= | Silent (SNP) | VAF 38/370 reads (10%) | catalogued as rs781797755; called by muse, mutect2, varscan2
- CLDND2 | c.96C>A p.T32= | Silent (SNP) | VAF 126/401 reads (31%) | called by muse, mutect2, varscan2
- COL17A1 | c.4323G>C p.G1441= | Silent (SNP) | VAF 62/796 reads (8%) | called by muse, mutect2
- CSMD1 | c.6183C>A p.T2061= (on ENST00000520002; = p.T2060= on NM_033225.6) | Silent (SNP) | VAF 36/452 reads (8%) | catalogued as rs1187464582; called by muse, mutect2
- CTAGE15 | c.60C>G p.R20= | Silent (SNP) | VAF 55/1570 reads (4%) | called by muse, mutect2
- DAAM2 | c.2349G>T p.L783= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2
- DGKI | c.1350G>T p.L450= | Silent (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2, varscan2
- DLGAP2 | c.682C>A p.R228= | Silent (SNP) | VAF 24/248 reads (10%) | catalogued as rs1428611888; called by muse, mutect2, varscan2
- DLGAP4 | c.579C>A p.P193= | Silent (SNP) | VAF 71/416 reads (17%) | called by muse, mutect2, varscan2
- DNHD1 | c.3915C>T p.D1305= | Silent (SNP) | VAF 31/241 reads (13%) | called by muse, mutect2, varscan2
- EFCAB8 | c.486G>A p.K162= | Silent (SNP) | VAF 23/306 reads (8%) | catalogued as rs950273646; called by muse, mutect2
- EFHB | c.1617A>C p.R539= | Silent (SNP) | VAF 17/206 reads (8%) | called by muse, mutect2
- EHD2 | c.1116C>T p.H372= | Silent (SNP) | VAF 51/775 reads (7%) | catalogued as rs1314931982; called by muse, mutect2
- EIF4A2 | c.279A>G p.Q93= | Silent (SNP) | VAF 28/456 reads (6%) | catalogued as rs11538616; called by muse, mutect2
- EPHB4 | c.633G>T p.V211= | Silent (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- FAM186A | c.219A>C p.I73= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- FAM47C | c.456G>A p.P152= | Silent (SNP) | VAF 23/272 reads (8%) | catalogued as rs782651418, COSV63725345, COSV63730617; called by muse, mutect2
- FREM3 | c.4791C>A p.T1597= | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs551388613; called by muse, mutect2, varscan2
- GALNT3 | c.646C>T p.L216= | Silent (SNP) | VAF 38/313 reads (12%) | called by muse, mutect2, varscan2
- GDF10 | c.999C>A p.P333= | Silent (SNP) | VAF 32/261 reads (12%) | catalogued as rs782222551; called by muse, mutect2, varscan2
- GPR156 | c.2193C>G p.P731= | Silent (SNP) | VAF 42/154 reads (27%) | called by muse, mutect2, varscan2
- HTR3B | c.807C>A p.A269= | Silent (SNP) | VAF 184/814 reads (23%) | called by muse, mutect2, varscan2
- IFNA16 | c.90C>T p.H30= | Silent (SNP) | VAF 37/209 reads (18%) | catalogued as rs757504584; called by muse, varscan2
- IGHV1OR15-9 | c.141C>A p.T47= | Silent (SNP) | VAF 40/608 reads (7%) | called by muse, mutect2
- IGLV2-33 | c.87G>T p.V29= | Silent (SNP) | VAF 32/278 reads (12%) | catalogued as rs1338475275; called by muse, mutect2, varscan2
- IHH | c.1017G>A p.V339= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- IQCG | c.1041T>A p.A347= | Silent (SNP) | VAF 52/309 reads (17%) | called by muse, mutect2, varscan2
- IRAK1 | c.42C>G p.G14= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.1392G>C p.L464= | Silent (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- KCNH1 | c.1695C>T p.A565= (on ENST00000271751 / NM_172362.3; = p.A538= on NM_002238.4) | Silent (SNP) | VAF 46/244 reads (19%) | catalogued as rs779603628, COSV55087253; called by muse, mutect2, varscan2
- LCT | c.2493C>A p.P831= | Silent (SNP) | VAF 42/369 reads (11%) | called by muse, mutect2, varscan2
- LMBR1 | c.28C>A p.R10= | Silent (SNP) | VAF 57/337 reads (17%) | called by muse, mutect2, varscan2
- LMX1A | c.454C>A p.R152= | Silent (SNP) | VAF 77/354 reads (22%) | catalogued as rs559035208, COSV54224377; called by muse, mutect2, varscan2
- LY9 | c.963C>A p.S321= | Silent (SNP) | VAF 74/427 reads (17%) | called by muse, mutect2, varscan2
- MRGPRD | c.711G>A p.L237= | Silent (SNP) | VAF 18/227 reads (8%) | catalogued as rs1343687238, COSV100483085; called by muse, mutect2
- MUC19 | c.1428T>A p.I476= | Silent (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- MYO5B | c.522G>A p.K174= | Silent (SNP) | VAF 46/579 reads (8%) | called by muse, mutect2
- MYPN | c.588C>T p.S196= | Silent (SNP) | VAF 25/410 reads (6%) | catalogued as rs753313639; called by muse, mutect2
- NCKAP5 | c.942A>G p.K314= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs201246754; called by muse, mutect2, varscan2
- NMBR | c.978A>T p.L326= | Silent (SNP) | VAF 23/164 reads (14%) | called by muse, mutect2, varscan2
- NTRK3 | c.2244T>A p.T748= (on ENST00000360948 / NM_001012338.2; = p.T734= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/335 reads (10%) | called by muse, mutect2, varscan2
- OR2AK2 | c.615T>A p.I205= | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- OR4C12 | c.645C>A p.S215= | Silent (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- OR5M1 | c.609A>T p.A203= | Silent (SNP) | VAF 22/286 reads (8%) | called by muse, mutect2
- OSBPL5 | c.1911G>A p.V637= | Silent (SNP) | VAF 53/267 reads (20%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.261G>T p.A87= | Silent (SNP) | VAF 59/286 reads (21%) | catalogued as COSV53891890; called by muse, mutect2, varscan2
- PDIA4 | c.651G>A p.E217= | Silent (SNP) | VAF 48/528 reads (9%) | called by muse, mutect2
- PIF1 | c.1608C>A p.G536= | Silent (SNP) | VAF 62/442 reads (14%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.5460C>T p.G1820= | Silent (SNP) | VAF 21/215 reads (10%) | catalogued as COSV65745899; called by muse, mutect2
- PLA2G4F | c.385C>T p.L129= | Silent (SNP) | VAF 34/414 reads (8%) | catalogued as rs747574783; called by muse, mutect2
- RIC3 | c.60G>C p.S20= | Silent (SNP) | VAF 26/312 reads (8%) | called by muse, mutect2
- RPUSD3 | c.484C>A p.R162= | Silent (SNP) | VAF 19/302 reads (6%) | called by muse, mutect2
- SAGE1 | c.837G>T p.V279= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- SAGE1 | c.2049T>C p.N683= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- SALL3 | c.1563C>A p.T521= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV73305716; called by muse, mutect2, varscan2
- SIGMAR1 | c.420C>T p.T140= | Silent (SNP) | VAF 76/508 reads (15%) | called by muse, mutect2, varscan2
- SLC26A8 | c.1320G>A p.L440= | Silent (SNP) | VAF 24/358 reads (7%) | called by muse, mutect2
- SLC4A3 | c.3381G>C p.L1127= | Silent (SNP) | VAF 28/299 reads (9%) | called by muse, mutect2
- SP110 | c.1468C>A p.R490= | Silent (SNP) | VAF 54/462 reads (12%) | catalogued as rs201376755; called by muse, mutect2, varscan2
- SULF1 | c.2455C>A p.R819= | Silent (SNP) | VAF 14/186 reads (8%) | catalogued as COSV52679925; called by muse, mutect2
- TJP1 | c.1707A>T p.V569= | Silent (SNP) | VAF 37/177 reads (21%) | called by muse, mutect2, varscan2
- TMEM44 | c.51G>T p.L17= | Silent (SNP) | VAF 57/408 reads (14%) | called by muse, mutect2, varscan2
- TMLHE | c.828T>C p.Y276= | Silent (SNP) | VAF 12/264 reads (5%) | catalogued as rs781824393, COSV100545097; called by muse, mutect2
- TNFSF15 | c.375G>T p.L125= | Silent (SNP) | VAF 28/267 reads (10%) | catalogued as rs568808241; called by muse, varscan2
- TNMD | c.855C>A p.G285= | Silent (SNP) | VAF 18/350 reads (5%) | called by muse, mutect2
- TRAV8-7 | c.312T>A p.A104= | Silent (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- TRPC3 | c.480G>A p.L160= (on ENST00000379645 / NM_001366479.2; = p.L87= on NM_003305.2) | Silent (SNP) | VAF 11/110 reads (10%) | catalogued as COSV53382612; called by muse, mutect2, varscan2
- TSHZ2 | c.2085C>A p.L695= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- UBOX5 | c.1479C>T p.Y493= | Silent (SNP) | VAF 90/649 reads (14%) | catalogued as rs1443362389; called by muse, mutect2, varscan2
- USH2A | c.13389C>A p.T4463= | Silent (SNP) | VAF 57/406 reads (14%) | catalogued as CD149998; called by muse, mutect2, varscan2
- USP11 | c.1182G>T p.L394= (on ENST00000218348; = p.L351= on NM_001371072.1) | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- WDCP | c.474C>T p.R158= | Silent (SNP) | VAF 43/538 reads (8%) | called by muse, mutect2
- WDR62 | c.1482G>T p.G494= | Silent (SNP) | VAF 145/461 reads (31%) | catalogued as COSV54336433; called by muse, mutect2, varscan2
- ZNF233 | c.900G>T p.G300= | Silent (SNP) | VAF 19/261 reads (7%) | called by muse, mutect2
- ZNF671 | c.1296G>A p.K432= | Silent (SNP) | VAF 53/214 reads (25%) | called by muse, mutect2, varscan2
- ZNF98 | c.720C>T p.C240= | Silent (SNP) | VAF 29/224 reads (13%) | catalogued as rs370915484, COSV99078221; called by muse, mutect2, varscan2
- ADORA1 | c.342-14569G>T | Intron (SNP) | VAF 56/312 reads (18%) | called by muse, mutect2, varscan2
- ANO7 | c.471+33G>A | Intron (SNP) | VAF 30/305 reads (10%) | called by muse, mutect2
- ANTXR2 | c.*34T>G | 3'UTR (SNP) | VAF 20/304 reads (7%) | called by muse, mutect2
- APLN | c.*137T>G | 3'UTR (SNP) | VAF 66/854 reads (8%) | called by muse, mutect2
- BDNF | c.*11T>C | 3'UTR (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- BTD | c.-334G>T | 5'UTR (SNP) | VAF 61/337 reads (18%) | called by muse, mutect2, varscan2
- CCDC13 | c.603+1986G>T | Intron (SNP) | VAF 53/284 reads (19%) | called by muse, mutect2, varscan2
- CCER1 | chr12:90947889 T>C | 3'Flank (SNP) | VAF 58/316 reads (18%) | catalogued as rs1277099539; called by muse, mutect2, varscan2
- CD5L | c.*34C>A | 3'UTR (SNP) | VAF 5/42 reads (12%) | catalogued as rs1438490012; called by muse, mutect2, varscan2
- CRIP2 | chr14:105473377 G>T | 5'Flank (SNP) | VAF 86/493 reads (17%) | called by muse, mutect2, varscan2
- DST | c.414+7060G>C | Intron (SNP) | VAF 44/219 reads (20%) | called by muse, mutect2, varscan2
- ELP3 | c.-23G>A | 5'UTR (SNP) | VAF 31/480 reads (6%) | catalogued as rs773827283; called by muse, mutect2
- ENPEP | c.1510-953G>T | Intron (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- FOLH1B | n.1989G>T | RNA (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- GJA9 | c.-150C>G | 5'UTR (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- GRID1 | c.236-58060G>C | Intron (SNP) | VAF 54/579 reads (9%) | called by muse, mutect2
- GUK1 | c.-3+506A>T | Intron (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- HNRNPA3P1 | n.714C>T | RNA (SNP) | VAF 44/388 reads (11%) | catalogued as rs1454579532; called by muse, mutect2, varscan2
- IGFBP1 | c.-11C>A | 5'UTR (SNP) | VAF 38/406 reads (9%) | catalogued as rs1400457107; called by muse, mutect2
- JPH3 | c.2167-696C>A | Intron (SNP) | VAF 35/410 reads (9%) | catalogued as COSV52472835; called by muse, mutect2
- KIF21B | c.900+15G>A | Intron (SNP) | VAF 18/412 reads (4%) | called by muse, mutect2
- KIR2DL4 | c.927+63C>A | Intron (SNP) | VAF 163/938 reads (17%) | catalogued as COSV100428574; called by muse, mutect2, varscan2
- KRTAP5-2 | chr11:1598314 G>C | 5'Flank (SNP) | VAF 30/392 reads (8%) | called by muse, mutect2
- LBHD1 | c.617-477C>G | Intron (SNP) | VAF 36/173 reads (21%) | catalogued as rs951352209; called by muse, mutect2, varscan2
- LINC00482 | n.1023G>T | RNA (SNP) | VAF 71/423 reads (17%) | called by muse, mutect2, varscan2
- LRRC37A6P | n.1821C>G | RNA (SNP) | VAF 34/462 reads (7%) | called by muse, mutect2
- LRRC37A6P | n.1820G>A | RNA (SNP) | VAF 34/464 reads (7%) | catalogued as rs748506247; called by muse, mutect2
- LRRC49 | c.105+990C>T | Intron (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2, varscan2
- MAGEA5 | n.149T>A | RNA (SNP) | VAF 15/232 reads (6%) | called by muse, mutect2
- MELTF | c.712+1651G>A | Intron (SNP) | VAF 20/246 reads (8%) | called by muse, mutect2
- MINDY3 | c.462-270A>G | Intron (SNP) | VAF 22/144 reads (15%) | called by muse, varscan2
- MIR892B | n.52C>A | RNA (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- MIR9-1HG | n.338C>A | RNA (SNP) | VAF 32/327 reads (10%) | called by muse, mutect2
- MS4A1 | c.574-24C>A | Intron (SNP) | VAF 26/444 reads (6%) | called by muse, mutect2
- MS4A6A | c.283-491G>T | Intron (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- NDUFS8 | c.58+27G>T | Intron (SNP) | VAF 103/554 reads (19%) | called by muse, mutect2, varscan2
- NHSL2 | chrX:72143368 G>C | 3'Flank (SNP) | VAF 25/327 reads (8%) | called by muse, mutect2
- NVL | c.961-1100C>A | Intron (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- OFD1 | c.*46C>T | 3'UTR (SNP) | VAF 22/172 reads (13%) | catalogued as rs1280404969, COSV57422526; called by muse, mutect2, varscan2
- OR10D1P | n.590G>T | RNA (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- OR10Z1 | chr1:158611435 T>C | 3'Flank (SNP) | VAF 15/83 reads (18%) | catalogued as rs769959795, COSV63525914; called by muse, mutect2, varscan2
- OR51F5P | n.336G>A | RNA (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- PCDHA9 | c.2394+72G>A | Intron (SNP) | VAF 28/112 reads (25%) | called by muse, mutect2
- PDXK | c.88-1544G>T | Intron (SNP) | VAF 76/935 reads (8%) | catalogued as rs758952228; called by muse, mutect2
- PNMA3 | c.*97A>T | 3'UTR (SNP) | VAF 11/246 reads (4%) | catalogued as COSV100937696; called by muse, mutect2
- PRKG1 | c.478+146253G>T | Intron (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- RAB18 | c.-22C>G | 5'UTR (SNP) | VAF 52/744 reads (7%) | catalogued as rs549858585; called by muse, mutect2
- RASSF4 | c.63-201A>T | Intron (SNP) | VAF 45/331 reads (14%) | catalogued as rs1292905481; called by muse, mutect2, varscan2
- RGS2 | c.-16C>T | 5'UTR (SNP) | VAF 66/554 reads (12%) | catalogued as rs1324682377; called by muse, mutect2, varscan2
- RXRG | c.49+7702G>C | Intron (SNP) | VAF 20/193 reads (10%) | called by muse, mutect2
- SCN4B | c.*609C>A | 3'UTR (SNP) | VAF 50/480 reads (10%) | called by muse, mutect2
- SLC38A1 | c.1362+1574G>T | Intron (SNP) | VAF 17/236 reads (7%) | called by muse, mutect2
- SNORD114-12 | n.31A>T | RNA (SNP) | VAF 19/222 reads (9%) | called by muse, mutect2
- SNORD115-21 | chr15:25208170 G>T | 3'Flank (SNP) | VAF 68/392 reads (17%) | called by muse, mutect2, varscan2
- SORBS2 | c.684+7668G>T | Intron (SNP) | VAF 16/274 reads (6%) | called by muse, mutect2
- SORBS2 | c.684+7667G>T | Intron (SNP) | VAF 16/272 reads (6%) | called by muse, mutect2
- SP140 | c.*51C>A | 3'UTR (SNP) | VAF 25/233 reads (11%) | catalogued as rs1387611701; called by muse, mutect2, varscan2
- TBC1D15 | c.30+14992G>C | Intron (SNP) | VAF 46/290 reads (16%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.617-33G>A | Intron (SNP) | VAF 37/293 reads (13%) | called by muse, mutect2, varscan2
- TPM2 | c.563+43G>T | Intron (SNP) | VAF 109/522 reads (21%) | called by muse, mutect2, varscan2
- TTC3P1 | n.5204C>T | RNA (SNP) | VAF 14/206 reads (7%) | catalogued as rs1451769338; called by muse, mutect2
- UHRF1BP1L | c.*30G>T | 3'UTR (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- UQCRB | c.258+43T>C | Intron (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
